Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6311, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6311-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. RIGHT COLON

SPECIMEN(S):

A. RIGHT COLON

GROSS DESCRIPTION:

A. RIGHT COLON

Received fresh is a right hemicolectomy specimen consisting of a segment of large intestine measuring 22 x 8.5 cm (circumference) and portion of distal ileum measuring 1 x 3.2 cm (circumference). No appendix is seen grossly. The large intestine contains an exophytic tumor measuring 3.9 x 3.2 x 0.5 cm and located 4.5 cm from the ileocecal valve. The serosal surface corresponding to tumor area is inked black. The tumor appears to invade muscularis propria grossly. The ileocecal valve mucosa has a slightly sessile polypoid granular area; this area measures 2.0 x 2.0 x 1.3 cm. There is another possible polyp located 4.8 cm from the first polyp and is located 3.1 cm distally from the tumor; this polyp measures 2.0 x 1.5 x 0.4 cm. The pericolic fat is submitted in O-fix for overnight fixation; multiple lymph nodes are found, they range from 0.1 to 0.5 cm in diameter. A portion of the tumor is submitted for tissue procurement. Representative sections are submitted in A1 (distal margin, shaved section), A2-A3 (ileocecal valve granular area), A4-A12 (entire tumor), A13 (another polyp toward the distal margin), A14-A15 (random mucosa), A16-A40 (lymph nodes), and A41 (proximal margin, shaved section).

DIAGNOSIS:

A. COLON, RIGHT, HEMICOLECTOMY:

- INVASIVE MODERATELY TO POORLY DIFFERENTIATED ADENOCARCINOMA INVADING SUBSEROSEA
- TUMOR SIZE 3.9 X 3.2 X 0.5 CM
- METASTATIC CARCINOMA TO ONE OUT OF THIRTY SEVEN LYMPH NODES (1/37). THE INVOLVED LYMPH NODE SIZE 0.4 CM AND LOCATED IN PERICOLIC FAT UNDERLYING THE INVASIVE CARCINOMA
- SURGICAL MARGINS NEGATIVE FOR CARCINOMA

- MULTIPLE TUBULAR ADENOMAS (LOCATED AT THE ILEOCECAL VALVE AND ADJACENT TO THE INVASIVE CARCINOMA)
- HYPERPLASTIC POLYP
- SEE SYNOPTIC REPORT

SYNOPTIC REPORT - COLON & RECTUM

Specimen Type: Right hemicolectomy

Tumor Site: Right (ascending) colon

Tumor Configuration: Infiltrative

Tumor size: 3.9cm Additional dimensions 3.2cm x 0.5cm

WHO Classification

Adenocarcinoma 8140/3

Histologic Grade: G3: Poorly differentiated

Extent of Invasion: Subserosa

Margins: Margin(s) uninvolved by invasive carcinoma (Proximal, Distal, Radial)

Venous/Lymphatic Invasion: Present

Perineural Invasion: Present

Additional Pathologic Findings: Adenoma

Hyperplastic polyp

Extent of Resection: R0: Complete resection with grossly and microscopically negative margins

Lymph Nodes: Positive 1 / 37

Extranodal extension: Absent

Implants: Absent

Pathological Staging (pTNM): pT 3 N 1 M x

CLINICAL HISTORY:

None provided

PRE-OPERATIVE DIAGNOSIS:

Colon cancer

[page 2 of 2]
ADDENDUM:

ANALYSIS OF MISMATCH REPAIR PROTEIN EXPRESSION

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block A9

Population: Tumor Cells

Stain/Marker:	Result:	Comment:
MSH2		Positive
MSH6		Positive
MLH1		Positive
PMS2		Positive

The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within the Immunohistochemistry Laboratory of the. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by the Department of Pathology Laboratory at. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

INTERPRETATION: No abnormalities in mismatch repair protein expression identified.

Expression of MLH1, MSH2, MSH6, and PMS2 in the tumor was evaluated by immunohistochemistry. Peritumoral lymphocytes and normal glands serve as internal positive controls expressing MLH1, MSH2, MSH6, and PMS2.

Testing for Microsatellite Instability has been ordered. The results will be issued in a separate report.

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 53e1d4d9-4d90-4ebb-8c2b-cd13bbe12507 (TCGA-G4-6311.9B738535-D694-4F0E-9FAD-F2E67D9FF126.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).